Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4C9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4C9-01A (Primary Tumor).

[page 1 of 8]
Department of Pathology

Patient Name: [REDACTED] Copath #: [REDACTED]
MRN: [REDACTED] Service: Otolaryngology Collected: [REDACTED]
DOB: [REDACTED] Visit #: [REDACTED] Resulted: [REDACTED]
Gender: [REDACTED] Location: [REDACTED]
HCN: [REDACTED] Facility: [REDACTED]
Ordering MD: [REDACTED]

Surgical Pathology Consultation Report

* Addended *

ICD-0-3

SPECIMEN(S) RECEIVED

1. Salivary-Gland: RIGHT PAROTID
2. Neck: Rt. neck level I
3. Neck: Rt. neck level II
4. Neck: Rt. neck level II
5. Neck: Rt. neck level IV
6. Neck: Left neck level I and II
7. Oral Cavity: Ventral tongue margin
8. Oral Cavity: Rt. posterior margin
9. Oral Cavity: Lt. posterior margin
10. Oral Cavity: Anterior floor of mouth, ventral tongue and marginal
mandibulectomy
11. Oral Cavity: Lt. level II tissue

carcinoma, Squamous cell, NOS 8070/3
Site: Mouth, floor, anterior C04.0

pw 9/26/12

DIAGNOSIS

1. Right parotid gland.
Multifocal Warthin's tumor.
- a. Largest tumor measures 2.0 cm.
- b. Warthin's tumor present in three intraparotid/periparotid lymph
nodes.
- c. Negative for squamous cell carcinoma.

2, 3, 4, 5 and 6. lymph nodes; right neck levels I-VB and left neck
levels I and II.

One of forty-six lymph nodes positive for metastatic squamous cell
carcinoma (1/46).

- a. The involved lymph node measures 1.3 cm.
- b. Positive for focal extracapsular invasion.
- c. The involved lymph node is in right level I.
- Submandibular glands with no pathologic changes.

7. Ventral tongue margin.
Squamous mucosa negative for malignancy.

[page 2 of 8]
Patient Name	[REDACTED]	Copath #:	[REDACTED]
MRN:	[REDACTED]	Service: Otolaryngology	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	Resulted: [REDACTED]
HCN:	[REDACTED]	Facility:	
Ordering MD:	[REDACTED]		

8. Right posterior margin.
Squamous mucosa negative for malignancy.

9. Left posterior margin.
Negative for malignancy

10. Oral cavity; anterior floor of mouth, ventral tongue and marginal mandibulectomy
Squamous cell carcinoma, moderately differentiated.
a. Maximum tumor dimension 3.6 cm.
b. Tumour thickness 2.0 cm.
c. Negative for perineural invasion.
d. Negative for lymphovascular invasion.
e. Margins are negative for tumor. The deep margin is close (0.5 cm) to tumor.
f. One lymph node negative for carcinoma (0/1).
g. Decalcified sections of mandible are pending. An addendum report will follow.

11. Left level II tissue
Adipose tissue with no pathologic changes.
Negative for tumor.

SYNOPTIC DATA

Specimen:
otherwise specified (NOS)

Received:
Procedure:
of mouth

bilateral: right (zones I-VB) and left (zones I and II)
Specimen Size:

Ventral surface of tongue, not

Anterior floor of mouth
Fresh
Glossectomy: ventral tongue, floor

Neck (lymph node) dissection:
Greatest dimension: 6.0 cm

[page 3 of 8]
Specimen Laterality:
Tumor Site:

Tumor Focality:
Tumor Size:

Additional dimension: 12 cm
Additional dimension: 9.0 cm
Midline
Ventral surface of tongue, NOS
Anterior floor of mouth
Single focus
Greatest dimension: 2.0 cm

Status: supplemental

Page: 2 of 7

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath # [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

Histologic Type:

Histologic Grade:

Margins:
carcinoma

Additional dimension: 3.6 cm
Additional dimension: 2.4 cm
Squamous cell carcinoma, conventional

G2: Moderately differentiated
Margins uninvolved by invasive

Distance from closest margin: 0.5 cm

Margin(s): deep
Margin status for carcinoma in situ

is not applicable

Lymph-Vascular Invasion:

Perineural Invasion:

Lymph Nodes, Extranodal Extension:

TNM Descriptors:

Primary Tumor (pT):

more than 4 cm in greatest dimension

Regional Lymph Nodes (pN):

ipsilateral lymph node, 3 cm or less

examined: 47

involved: 1

Distant Metastasis (pM):

Not identified

Not identified

Present

Not applicable

pT2: Tumor more than 2 cm but not

pN1: Metastasis in a single
in greatest dimension

Number of regional lymph nodes

Number of regional lymph nodes

Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 4 of 8]
ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "right parotid". It consists of an unoriented parotid gland and adjacent soft tissues measuring 6.5 x 5.5 x 1.8 cm. The parotid shows a tumor measuring 2.0 x 1.3 x 1.1 cm. The tumor is well circumscribed and firm. It is located at 0.3 cm from the deep margin and 0.6 cm from the

Status: supplemental

Page: 3 of 7

Patient Name:	[REDACTED]	Copath #:	[REDACTED]
MRN:	[REDACTED]	Service: Otolaryngology	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	[REDACTED]
HCN:	[REDACTED]	Facility:	[REDACTED]
Ordering MD:	[REDACTED]		

superficial margin. The remaining parotid is grossly unremarkable. Multiple intraparotid lymph nodes measuring from 0.5 to 2.3 cm are identified. One piece of tumor and one piece of normal tissue are stored frozen. Representative sections are submitted.

1A tumor with deep and superficial margins
1B tumor with normal parotid
1C normal parotid
1D one lymph node
1E-1F one lymph node bisected in each
1G-1H one lymph node bisected

2. The specimen is labeled with the patient's name and as "right neck level I". It consists of fibroadipose tissue measuring 5.3 x 4.0 x 3.4 cm. The submandibular gland measures 4.5 x 3.6 x 1.9 cm and is grossly unremarkable. Multiple lymph nodes ranging from 0.4 to 1.9 cm are identified. Representative sections are submitted.

2A submandibular gland
2B fibroadipose tissue
2C two lymph nodes
2D-2E one node bisected each block

3. The specimen is labeled with the patient's name and as "right neck

[page 5 of 8]
level II". It consists of a portion of fibroadipose and muscle tissue measuring 8.4 x 3.2 x 1.7 cm. Multiple lymph nodes ranging from 0.3 to 1.4 cm in greatest dimension are identified. Representative sections are submitted.

3A three lymph nodes

3B one lymph node

4. The specimen is labeled with the patient's name and as "right neck level III/V B". It consists of a portion of fibroadipose tissue measuring 6.0 x 4.1 x 1.5 cm. Multiple lymph nodes ranging from 0.7 to 3.8 cm in greatest dimension are identified. Representative sections are submitted.

4A two lymph nodes

4B one lymph node bisected

4C-4E one lymph node trisected

5. The specimen is labeled with the patient's name and as "right neck level IV/V B. ". It consists of a portion of fibroadipose tissue measuring 8.7 x 4.7 x 1.6 cm. Multiple lymph nodes ranging from 0.3 to

Status: supplemental

Page: 4 of 7

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Service: Otolaryngology

Visit #: [REDACTED]

Location:

Facility:

Copath #: [REDACTED]

Collected: [REDACTED]

Resulted: [REDACTED]

2.1 cm in greatest dimension are identified. Representative sections are submitted.

5A six lymph nodes

5B five lymph nodes

5C six lymph nodes

5D five lymph nodes

5E four lymph nodes

5F one lymph node

6. The specimen is labeled with the patient's name and as "left neck level I and II". It consists of a portion of fibroadipose tissue measuring 6.9 x 5.0 x 3.4 cm. The submandibular gland measures 4.2 x 3.1 x 2.6 cm. Multiple lymph nodes ranging from 0.7 to 3.1 cm in greatest dimension are identified. Representative sections are submitted.

6A-6B submandibular gland

6C three lymph nodes

[page 6 of 8]
6D-6F one lymph node bisected per block
6G- 6H one lymph node bisected

7. The specimen is labeled with the patient's name and as "ventral tongue margin". It consists of a fragment of tissue measuring 2.1 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.
7A frozen section control

8. The specimen is labeled with the patient's name and as "right posterior margin". It consists of two fragments of tissue measuring from 0.5 x 0.3 x 0.2 to 1.0 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.
8A frozen section control

9. The specimen is labeled with the patient's name and as "left posterior margin". It consists of a fragment of tissue measuring 1.2 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.
9A frozen section control

10. The specimen is labeled the patient's name and as "anterior floor of mouth, ventral common and marginal mandibulectomy". It consists of an unoriented portion of ventral tongue measuring 2.5 cm SI x 6.0 cm ML x 6.0 cm AP. The portion of mandible measures 1.3 cm SI x 5.4 cm ML x 1.0 cm AP. The right posterior inferior aspect of the mandible is fragmented. The right ventral tongue measures 0.5 cm SI x 5.1 cm ML x

Status: supplemental

Page: 5 of 7

Patient Name: [REDACTED]	Service: Otolaryngology	Copath # [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

2.1 cm AP. The floor of mouth measures 2.5 cm SI x 6.2 cm ML x 2.6 cm AP. There is an ulcerated tumor involving the right floor of mouth. The tumor measures 2.0 cm SI x 3.6 cm ML x 2.4 cm AP. The tumor is ill-defined and firm. It is located at 0.8 cm from the lateral mucosal margin, 1.5 cm from the medial soft tissue margin, 0.8 cm from the medial mucosal margin, 0.5 cm from the deep margin, 1.1 cm from the anterior mucosal margin, 1.8 cm from the posterior soft tissue margin, 1.4 cm from the superior soft tissue margin, 1.8 cm from the left medial mandibular bony margin, 1.1 cm from the anterior inferior mandibular bony margin, and 1.3 cm from the fragmented posterior inferior mandibular bony

[page 7 of 8]
margin. Possible involvement of the bone is grossly identified. One lymph node is identified measuring 0.5 x 0.4 x 0.3 cm. The deep margin is painted with green dye. Two perpendicular sections are taken from deep margin for frozen section. One piece of tumor and one piece of tissue are stored frozen. Representative sections are submitted.

10A- 10B frozen section controls
10C anterior mucosal margin, shaved and bisected
10D lateral mucosal margin, shaved and bisected
10E tumor with superior, deep, and anterior mucosal margins
10F tumor with superior, deep and right lateral mucosal margins
10G tumor with inferior soft tissue margin
10H posterior soft tissue margin
10I one lymph node
10J left medial mandibular margin, en face after decalcification
10K right posterior inferior fragmented mandibular margin, after decalcification
10L-10M inferior mandibular margin, en face after decalcification
10N tumor with anterior mucosal and inferior mandibular margins, after decalcification
10O-10P tumor with mandible, after decalcification

11. The specimen is labeled with the patient's name and as "left level II tissue". It consists of oriented piece of adipose tissue measuring 1.5 x 0.8 x 0.4 cm. No lymph nodes are identified.

11A specimen in toto

QUICK SECTION

7A. negative for carcinoma

8A. negative for carcinoma

9A. negative for carcinoma

Status: supplemental

Page: 6 of 7

Patient Name	[REDACTED]	Copath #	[REDACTED]
MRN:	[REDACTED]	Service: Otolaryngology	Collected: [REDACTED]
DOB:	[REDACTED]	Visit #:	[REDACTED]
Gender:	[REDACTED]	Location:	Resulted: [REDACTED]
HCN:	[REDACTED]	Facility:	
Ordering MD:	[REDACTED]		

10A, 10B. negative for carcinoma
Time reported to surgeon:

[page 8 of 8]
Addendum Comment

Decalcified sections of the mandible show wide invasion of cortical and medullary bone by squamous cell carcinoma. The right inferior and posterior bone margins are positive for carcinoma.

Page: 7 of 7

8/23/12

Source: NCI Genomic Data Commons file 76eea0b6-d6bb-4054-851c-38925c44ac05 (TCGA-CQ-A4C9.3E92DE59-C77B-47B3-A11E-7EDEAFA9598C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).